Gene-level copy-number profile of tumor specimen TCGA-2G-AAFH-01A from TCGA case TCGA-2G-AAFH, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 38.7 years (14,120 days).
Specimen TCGA-2G-AAFH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.fb961b72-8d53-40e8-bccc-1831d381877a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AAFH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/261f1efd-d433-4089-9d5c-a9a39443750d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,803; copy number 2: 15,398; copy number 3: 22,271; copy number 4: 14,054; copy number 5: 3,976; copy number 6: 1,058; copy number 7: 402; copy number 8: 851.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AAFH-01A-12D-A42X-01): tumor purity 0.41, ploidy 3.09, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,253 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:78,017,055–96,377,920, 214 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr8:12,721,906–20,700,152, 111 genes, copy number 7 (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 8 (broad region; genes not listed).
- chr15:51,208,057–51,338,601, 1 gene, copy number 7 (within-gene range 5–7): CYP19A1.
- chr15:51,278,927–55,498,360, 76 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr22:25,756,318–25,756,669, 1 gene, copy number 8: AL022329.3.

Autosomal genes at a single copy (total copy number 1): 1,803. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
